Somatic mutation profile of tumor specimen TCGA-H4-A2HQ-01A (aliquot TCGA-H4-A2HQ-01A-11D-A17V-08) from TCGA case TCGA-H4-A2HQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.4 years (23,538 days).
Specimen TCGA-H4-A2HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41574404-3c0f-4b8b-b7f9-d288a481abd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H4-A2HQ-10A (Blood Derived Normal), aliquot TCGA-H4-A2HQ-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45e19ab9-5694-498d-9fcd-19c722da26be

The open-access MAF lists 495 somatic variants for this specimen: 360 protein-altering or splice-affecting, 124 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 307, Silent 124, Nonsense Mutation 32, Splice Site 10, Frame Shift Del 6, Intron 4, Splice Region 3, RNA 3, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 33/52 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MPI | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894494, CM981303, COSV60396663, COSV60397635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TULP1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906836, CM040811, COSV57691729, COSV57693922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV55298744; called by muse, mutect2, varscan2
- AADACL3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as COSV60200485; called by muse, mutect2, varscan2
- ACAP1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs749843922, COSV50142107; called by muse, mutect2, varscan2
- ACRBP | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57525431; called by muse, mutect2, varscan2
- ADAM7 | c.187A>T p.I63L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV51546758; called by muse, mutect2, varscan2
- ADAM7 | c.390-2A>C p.X130_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV51546763; called by muse, mutect2, varscan2
- ADAMTS16 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57007439, COSV99941473; called by muse, mutect2
- ADCY2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57899636, COSV99073547; called by muse, mutect2, varscan2
- ADGRG2 | c.2176G>T p.V726L (on ENST00000379869 / NM_001079858.3; = p.V723L on NM_005756.4) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868473650, COSV61341414; called by muse, mutect2, varscan2
- ADGRG3 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV59652713; called by muse, varscan2
- ADGRG7 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV56301420, COSV99841762; called by muse, mutect2, varscan2
- ADGRL3 | c.3057C>A p.F1019L (on ENST00000506720 / NM_001322402.2; = p.F951L on NM_015236.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV72231272; called by mutect2, varscan2
- ADGRV1 | c.18128T>A p.I6043N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV67995653; called by muse, mutect2, varscan2
- AMER2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV63439018, COSV63440317; called by muse, mutect2, varscan2
- AMFR | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV51924385; called by muse, mutect2, varscan2
- ANKRD13A | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55678404; called by muse, varscan2
- APCDD1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.066); catalogued as rs1361536724, COSV62373345; called by muse, mutect2, varscan2
- ARHGAP35 | c.4045G>A p.D1349N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs764344593; called by muse, mutect2
- ARRB1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757602765, COSV63577624; called by muse, mutect2, varscan2
- ARVCF | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54270236; called by mutect2, varscan2
- ASS1 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 189/211 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61690765; called by muse, mutect2, varscan2
- ATP13A2 | c.2630G>C p.G877A | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58700191, COSV58703851; called by muse, mutect2, varscan2
- ATP2B4 | c.1624T>G p.F542V | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1209431907, COSV58184051; called by muse, mutect2, varscan2
- AURKC | c.581T>A p.L194Q (on ENST00000302804 / NM_001015878.2; = p.L160Q on NM_003160.3) | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV57137674, COSV57140284; called by muse, mutect2, varscan2
- BAZ2B | c.5648A>T p.N1883I | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58610149; called by muse, mutect2, varscan2
- BAZ2B | c.4506C>G p.N1502K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.206); catalogued as COSV58610156; called by muse, mutect2, varscan2
- BORA | c.1468G>C p.E490Q (on ENST00000613797; = p.E415Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV64695605, COSV64695902; called by muse, mutect2, varscan2
- BRPF1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100121282, COSV57408129; called by muse, mutect2, varscan2
- BTBD7 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV58288990, COSV58290541; called by muse, mutect2, varscan2
- BUD13 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV52768357; called by muse, mutect2, varscan2
- C16orf78 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753166935, COSV54557515; called by muse, mutect2, varscan2
- C1QBP | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV56709822; called by muse, mutect2, varscan2
- C3orf70 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58590677; called by muse, mutect2, varscan2
- C4BPA | c.42A>C p.K14N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV65537668; called by muse, mutect2, varscan2
- CABIN1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54089299; called by muse, mutect2, varscan2
- CBFA2T2 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60075949; called by muse, mutect2, varscan2
- CCN5 | c.635T>A p.M212K | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV51939396; called by muse, mutect2, varscan2
- CDH1 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs876661106, COSV55734508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH12 | c.1196T>A p.V399E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV66405825, COSV66448929; called by muse, mutect2, varscan2
- CDH23 | c.8234C>T p.T2745I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV56490543; called by muse, mutect2, varscan2
- CDH7 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59893344, COSV59894401; called by mutect2, varscan2
- CDHR2 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV56145564; called by muse, mutect2, varscan2
- CELF5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV53015303; called by muse, mutect2, varscan2
- CELSR3 | c.1999G>T p.G667C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51153656; called by muse, mutect2, varscan2
- CFLAR | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57938892; called by muse, mutect2, varscan2
- CHD7 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV71114618; called by mutect2, varscan2
- CHFR | c.1492G>C p.E498Q (on ENST00000432561 / NM_001161345.1; = p.E457Q on NM_018223.2) | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57174074, COSV57178050; called by muse, mutect2, varscan2
- CHL1 | c.2128+2T>A p.X710_splice (on ENST00000397491 / NM_001253387.1; = p.X726_splice on NM_006614.4) | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56606754; called by muse, mutect2, varscan2
- CHST8 | c.783C>G p.F261L | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV52862703, COSV52863347; called by muse, mutect2
- CLP1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745866505, COSV57055869; called by muse, mutect2, varscan2
- CNGB1 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51907172; called by muse, mutect2, varscan2
- CNMD | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV65034124; called by muse, mutect2, varscan2
- CNPY3 | c.178A>C p.K60Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.998); catalogued as COSV65710065; called by muse, mutect2, varscan2
- COL14A1 | c.796A>T p.I266F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52869026; called by muse, mutect2, varscan2
- COL21A1 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55180310; called by muse, mutect2, varscan2
- COL27A1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 183/454 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs369659292; called by muse, mutect2, varscan2
- COL4A3 | c.2660A>T p.E887V | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV67420375; called by muse, mutect2, varscan2
- COL7A1 | c.6368G>T p.G2123V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60403258; called by muse, mutect2, varscan2
- COPS4 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52317456; called by muse, mutect2, varscan2
- CPXM2 | c.2022C>A p.N674K | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV53860877, COSV53871225; called by muse, mutect2, varscan2
- CSMD2 | c.2017T>A p.S673T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV53938680, COSV53964293; called by muse, mutect2, varscan2
- CSMD2 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV53964313; called by muse, mutect2, varscan2
- CSPP1 | c.2934C>G p.I978M (on ENST00000676605; = p.I937M on NM_024790.6) | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV51592761; called by muse, mutect2, varscan2
- CTNNA3 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1460001539, COSV65530034; called by muse, mutect2
- CTNND2 | c.2473G>T p.V825L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV58929017; called by muse, mutect2
- CTSG | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV53534876; called by mutect2, varscan2
- CUL7 | c.4496A>G p.N1499S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.089); catalogued as rs1469639093, COSV54822020; called by muse, mutect2, varscan2
- CYP51A1 | c.97T>G p.L33V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV50154189; called by muse, mutect2, varscan2
- CYRIB | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV63118645; called by muse, mutect2, varscan2
- DAGLA | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs748469506, COSV57199785; called by muse, mutect2, varscan2
- DARS2 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53409146; called by muse, mutect2
- DCLK1 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV55178971; called by muse, mutect2, varscan2
- DDX42 | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 88/136 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63791436; called by muse, mutect2, varscan2
- DDX54 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs753895243, COSV58376116; called by muse, mutect2, varscan2
- DEF6 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV57353918, COSV57355446, COSV99987842; called by muse, mutect2, varscan2
- DEFB128 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV57685931; called by muse, mutect2
- DHX30 | c.1018G>T p.E340* (on ENST00000445061 / NM_138615.3; = p.E301* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 37/65 reads (57%) | catalogued as COSV53136530; called by muse, mutect2, varscan2
- DMD | c.4117C>A p.Q1373K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.219); catalogued as CM100264, COSV63792253; called by muse, mutect2, varscan2
- DNAH3 | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54552349; called by muse, mutect2, varscan2
- DNAH7 | c.12007C>T p.P4003S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs765475024, COSV56786809; called by mutect2, varscan2
- DOP1B | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV67696223; called by muse, mutect2, varscan2
- DYNC1H1 | c.12769G>C p.D4257H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64142642; called by muse, mutect2, varscan2
- EIF2AK4 | c.3581G>C p.R1194T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55466540, COSV55474208; called by muse, mutect2, varscan2
- EML5 | c.4121G>C p.R1374T (on ENST00000380664; = p.R1382T on NM_183387.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61351970; called by muse, mutect2, varscan2
- EPHA7 | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1270091812, COSV65191904; called by muse, mutect2, varscan2
- ERC1 | c.3253G>A p.E1085K (on ENST00000360905 / NM_178040.4; = p.E1057K on NM_178039.4) | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV61699655; called by muse, mutect2, varscan2
- ERICH1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs762788275, COSV50641013; called by muse, mutect2, varscan2
- ESPL1 | c.3341A>T p.K1114M | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57763431; called by muse, mutect2, varscan2
- ETV5 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV60506794; called by muse, mutect2, varscan2
- EVC2 | c.2927C>G p.S976C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV60402821; called by muse, varscan2
- EZH2 | c.434T>A p.F145Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV57447555, COSV57463059, COSV57463180; called by mutect2, varscan2
- EZR | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61456183; called by mutect2, varscan2
- FAM126A | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69017070, COSV69017697; called by muse, mutect2, varscan2
- FAM135B | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52754165, COSV99423441; called by muse, mutect2
- FAM71B | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 133/158 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57231323; called by muse, mutect2, varscan2
- FAM71F1 | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 56/118 reads (47%) | catalogued as rs747024970; called by muse, mutect2, varscan2
- FAM71F1 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.978); catalogued as COSV59374952; called by muse, mutect2, varscan2
- FASTKD3 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV52946881; called by muse, mutect2, varscan2
- FAT3 | c.6846C>A p.D2282E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53165520; called by muse, mutect2, varscan2
- FBLN1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs755919374, COSV59942149; called by muse, mutect2, varscan2
- FFAR3 | c.763C>G p.P255A | Missense Mutation (SNP) | VAF 40/778 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59909735; called by muse, mutect2
- FNDC3A | c.745G>A p.D249N (on ENST00000492622 / NM_001079673.2; = p.D193N on NM_014923.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV65697018; called by mutect2, varscan2
- FOLR2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs1387846315, COSV53352495; called by muse, mutect2
- FPGT | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV63846811; called by muse, mutect2, varscan2
- FPR1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs764940294, COSV59050865, COSV59052341; called by muse, mutect2, varscan2
- GALNT17 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.877); catalogued as COSV61156162, COSV61190663; called by muse, mutect2, varscan2
- GCC2 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs780981207; called by mutect2, varscan2
- GCOM1 | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51098713; called by muse, mutect2, varscan2
- GEMIN8 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 128/155 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV60551006; called by muse, mutect2, varscan2
- GFOD2 | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV52059906; called by muse, mutect2, varscan2
- GGA3 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55459057; called by muse, mutect2, varscan2
- GLI3 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV67893346; called by muse, mutect2, varscan2
- GNAO1 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs758424351, COSV52614953; ClinVar: benign; called by muse, mutect2, varscan2
- GOLGA2 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57856271; called by muse, mutect2, varscan2
- GPAT2 | c.2344C>G p.Q782E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV64003960; called by muse, mutect2, varscan2
- GPR12 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV67344928; called by muse, mutect2, varscan2
- GRIN2B | c.1636T>A p.S546T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV74207920; called by muse, mutect2, varscan2
- H3C10 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV60798803; called by mutect2, varscan2
- HELZ2 | c.3865G>C p.E1289Q (on ENST00000467148 / NM_001037335.2; = p.E720Q on NM_033405.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV71296211; called by muse, mutect2, varscan2
- HEXB | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54670055; called by muse, varscan2
- HFM1 | c.2616A>G p.I872M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1454257848, COSV54037605; called by muse, mutect2, varscan2
- HIRA | c.494-1G>A p.X165_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | catalogued as COSV54279900; called by muse, mutect2, varscan2
- HIVEP3 | c.6128G>C p.R2043T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV56010543, COSV56023889; called by muse, mutect2, varscan2
- HNRNPH3 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as COSV56263310; called by muse, mutect2, varscan2
- HPD | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV56643755; called by muse, mutect2, varscan2
- HSD17B13 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV56345963; called by muse, mutect2, varscan2
- HSPA13 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV53466513; called by muse, mutect2, varscan2
- IFNL2 | c.225C>A p.C75* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1359050492; called by muse, mutect2
- IFTAP | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV57559916; called by mutect2, varscan2
- IL23R | c.1272T>G p.S424R | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV61376350; called by muse, mutect2, varscan2
- IL27RA | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 99/148 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as COSV54603280; called by muse, mutect2, varscan2
- IRX2 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1452266289, COSV57413198, COSV57413760; called by muse, mutect2
- ITPKA | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV53026452; called by muse, mutect2, varscan2
- ITPR1 | c.2455G>A p.D819N (on ENST00000354582; = p.D804N on NM_002222.7) | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs200199463, COSV56991470; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1118T>A p.L373H | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67348112; called by muse, mutect2, varscan2
- JAGN1 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV57062944; called by muse, mutect2
- KCNK15 | c.703A>C p.I235L | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV65720783; called by muse, mutect2, varscan2
- KIF17 | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV56122575; called by muse, mutect2, varscan2
- KLHL38 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV58089055; called by muse, mutect2, varscan2
- KMT2C | c.7507C>T p.Q2503* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV51493039; called by muse, mutect2, varscan2
- KRT36 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 109/171 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60204225; called by muse, mutect2, varscan2
- LCOR | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV63632608; called by muse, mutect2, varscan2
- LPA | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs767564396, COSV60310772, COSV60312703; called by muse, mutect2, varscan2
- LPAR3 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV65455176; called by muse, mutect2, varscan2
- LPP | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.157); catalogued as rs948128172, COSV57115331; called by muse, mutect2, varscan2
- LRP1B | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV67211907, COSV67275787; called by muse, mutect2, varscan2
- LRP2 | c.11868G>T p.W3956C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55574813; called by muse, mutect2, varscan2
- LRRC3 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52400164; called by muse, mutect2, varscan2
- LRRC7 | c.3247G>A p.E1083K (on ENST00000651989 / NM_001370785.2; = p.E1050K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs770637610, COSV50417462; called by muse, mutect2, varscan2
- LRRIQ3 | c.1187A>T p.K396I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as COSV63050159; called by muse, mutect2, varscan2
- LRRTM2 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 170/191 reads (89%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as rs562960503, COSV51219453; called by muse, mutect2, varscan2
- MAGEC3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV53578731; called by muse, mutect2, varscan2
- MANBA | c.1995C>G p.I665M (on ENST00000642252; = p.I619M on NM_005908.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56970630; called by muse, mutect2, varscan2
- MANSC1 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV67111527; called by muse, mutect2, varscan2
- MAP4K2 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs773457675, COSV53648599; called by muse, mutect2, varscan2
- MAPK8 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100827481, COSV64411057; called by muse, mutect2, varscan2
- MARCHF11 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV60135108; called by muse, mutect2, varscan2
- MCF2L | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV65100927; called by muse, mutect2, varscan2
- MED16 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs375657697; called by muse, mutect2, varscan2
- MICAL2 | c.4386G>C p.E1462D | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.296); catalogued as COSV56288701; called by muse, mutect2, varscan2
- MIIP | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52428843; called by muse, mutect2, varscan2
- MIS18BP1 | c.3152+2T>G p.X1051_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV60373577; called by muse, mutect2, varscan2
- MR1 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV51582255; called by muse, mutect2, varscan2
- MTA2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV53874784, COSV99604483; called by muse, mutect2, varscan2
- MTM1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782277980, CM030242, COSV60337796; called by muse, mutect2, varscan2
- MTMR12 | c.1172-1G>C p.X391_splice | Splice Site (SNP) | VAF 16/116 reads (14%) | catalogued as COSV53788137; called by muse, mutect2, varscan2
- MUC16 | c.23851A>T p.R7951W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV67494875; called by muse, mutect2, varscan2
- MUC17 | c.6061G>A p.E2021K | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV60303745; called by muse, mutect2, varscan2
- MYH1 | c.5768A>C p.K1923T | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56857197; called by muse, mutect2, varscan2
- MYH13 | c.4213G>T p.E1405* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV52836636; called by mutect2, varscan2
- MYH8 | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV67972694; called by muse, mutect2, varscan2
- MYLK2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65659995; called by muse, mutect2, varscan2
- MYO16 | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV51818571; called by muse, mutect2, varscan2
- NAGPA | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 67/332 reads (20%) | PolyPhen possibly damaging (0.76); catalogued as COSV56570319, COSV56570932; called by muse, mutect2, varscan2
- NANOG | c.54C>G p.D18E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV57552633; called by muse, mutect2, varscan2
- NCF2 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs145970396; called by muse, mutect2, varscan2
- NEK11 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as rs768799271; called by muse, mutect2, varscan2
- NMT1 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV51962845; called by muse, mutect2, varscan2
- NR1I2 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51783230; called by muse, mutect2, varscan2
- NUBP2 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV51904490; called by muse, mutect2, varscan2
- NUMA1 | c.2463G>T p.Q821H | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); catalogued as COSV61191221; called by muse, mutect2, varscan2
- NUP160 | c.2992-1G>T p.X998_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV104428986, COSV65856127; called by muse, mutect2, varscan2
- NXPH2 | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs774743114, COSV55647011; called by muse, mutect2, varscan2
- OR51I2 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58300322; called by muse, mutect2, varscan2
- OR5T1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.707); catalogued as COSV57304969; called by muse, varscan2
- OR6C76 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV60390079; called by muse, mutect2, varscan2
- OR9Q1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59038731, COSV59040427; called by muse, mutect2, varscan2
- ORMDL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV58346377; called by muse, mutect2, varscan2
- OSMR | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV57092088; called by muse, mutect2, varscan2
- OTOP1 | c.1542G>C p.E514D | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56396962; called by muse, mutect2, varscan2
- OXSM | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV55002694; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.259C>A p.Q87K (on ENST00000374531 / NM_001037293.2; = p.Q85K on NM_007203.5) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57132728; called by muse, mutect2, varscan2
- PCDHA9 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV65332951; called by muse, mutect2, varscan2
- PGLYRP3 | c.979del p.Q327Rfs*? | Frame Shift Del (DEL) | VAF 85/275 reads (31%) | catalogued as COSV51952958; called by mutect2, pindel, varscan2
- PHTF2 | c.953G>C p.G318A (on ENST00000248550 / NM_001366089.1; = p.G280A on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV50341190; called by muse, mutect2, varscan2
- PIGG | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1553875268, COSV56321515; called by muse, mutect2, varscan2
- PKD2L1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV58398996; called by muse, mutect2, varscan2
- PKDREJ | c.3990G>C p.Q1330H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV53551821, COSV53553273; called by muse, mutect2, varscan2
- PKHD1L1 | c.5999A>C p.N2000T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65753464; called by muse, mutect2, varscan2
- PLCH1 | c.2843A>T p.E948V (on ENST00000340059 / NM_001130960.2; = p.E940V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV58210335; called by muse, mutect2, varscan2
- PLEKHM2 | c.2971T>G p.F991V | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV53818530, COSV99606499; called by muse, mutect2, varscan2
- PLS3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV56779357, COSV56782335; called by muse, mutect2, varscan2
- PLVAP | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377500653, COSV53087836; called by muse, mutect2, varscan2
- PLXNB2 | c.2484G>T p.L828F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63784488; called by muse, varscan2
- PNLDC1 | c.1067T>G p.F356C | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51708079; called by muse, mutect2, varscan2
- POC5 | c.680G>A p.R227K (on ENST00000428202 / NM_001099271.2; = p.R202K on NM_152408.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV62807411; called by muse, mutect2
- POLQ | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs149007312; called by muse, mutect2, varscan2
- POLR1G | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756102625, COSV56236212, COSV56236870; called by muse, mutect2, varscan2
- POM121 | c.3341A>G p.N1114S (on ENST00000434423; = p.N849S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782153568, COSV57524041; called by muse, mutect2, varscan2
- PPM1A | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV57788649; called by muse, mutect2, varscan2
- PPP6R2 | c.2341G>A p.E781K (on ENST00000216061 / NM_001365836.1; = p.E754K on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53298585; called by muse, mutect2, varscan2
- PRAG1 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167004; called by muse, mutect2, varscan2
- PRDM16 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); catalogued as rs779535977, COSV54604583, COSV54608936; called by muse, mutect2, varscan2
- PREX1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 345/991 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1172591295, COSV64248827; called by muse, mutect2, varscan2
- PRKD3 | c.1296G>C p.L432= | Splice Region (SNP) | VAF 39/132 reads (30%) | catalogued as COSV52218689; called by muse, mutect2, varscan2
- PRMT8 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54219396; called by muse, mutect2, varscan2
- PRRC2A | c.4060C>G p.P1354A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV65687295, COSV65689042; called by muse, varscan2
- PRRC2A | c.4079G>C p.G1360A | Missense Mutation (SNP) | VAF 90/144 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65689050; called by muse, varscan2
- PSMC3 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54082624, COSV54082872; called by muse, mutect2
- PTK2 | c.2326C>G p.H776D | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV61792742; called by muse, mutect2, varscan2
- PTPN21 | c.3018G>T p.K1006N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60852167; called by muse, mutect2, varscan2
- PTPRZ1 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV66445746; called by muse, mutect2, varscan2
- PYGM | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779706675, COSV51228772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QSER1 | c.2164A>G p.N722D (on ENST00000399302; = p.N851D on NM_001076786.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV67901812; called by muse, mutect2, varscan2
- RAB11FIP5 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV50258850; called by muse, mutect2, varscan2
- RAB3D | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55793025; called by muse, mutect2, varscan2
- RAVER1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV50330156; called by muse, mutect2, varscan2
- RAVER2 | c.1585C>T p.L529F (on ENST00000294428 / NM_001366165.1; = p.L516F on NM_018211.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.758); catalogued as COSV53810923; called by muse, mutect2, varscan2
- REG1A | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV52071585; called by mutect2, varscan2
- RHOA | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV69042978; called by muse, mutect2, varscan2
- RIC3 | c.925G>T p.E309* (on ENST00000309737 / NM_001206671.4; = p.E308* on NM_024557.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/125 reads (31%) | catalogued as COSV58301620; called by muse, mutect2, varscan2
- RIN2 | c.1864G>C p.E622Q (on ENST00000255006 / NM_001242581.1; = p.E573Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54794366; called by muse, mutect2, varscan2
- RPIA | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52171860; called by muse, mutect2, varscan2
- RPL11 | c.372C>G p.I124M (on ENST00000374550 / NM_001199802.1; = p.I125M on NM_000975.5) | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as CM1511665, COSV65778350; called by muse, varscan2
- RPL15 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV57141039; called by muse, mutect2, varscan2
- RPL28 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV59805899; called by muse, mutect2, varscan2
- RPLP0 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV56114951; called by muse, mutect2, varscan2
- RPRD2 | c.2770G>A p.G924R | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV64823376; called by muse, mutect2, varscan2
- RTN1 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV50749585; called by muse, mutect2, varscan2
- SACS | c.10999C>T p.H3667Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66535511; called by mutect2, varscan2
- SACS | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV66544518; called by muse, mutect2, varscan2
- SCN1A | c.4611C>A p.F1537L (on ENST00000303395 / NM_001202435.3; = p.F1526L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV57664442, COSV57688162; called by muse, mutect2, varscan2
- SEMA4F | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV60285361; called by muse, mutect2, varscan2
- SERPINI2 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.575); catalogued as COSV52988951, COSV52989898; called by muse, mutect2, varscan2
- SI | c.2667A>T p.E889D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52301467; called by muse, mutect2, varscan2
- SIDT1 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV53507416; called by muse, mutect2, varscan2
- SIDT2 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54060949; called by muse, mutect2, varscan2
- SLC16A1 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1411342, COSV63710359; called by mutect2, varscan2
- SLC24A5 | c.1306A>G p.R436G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51053959; called by muse, mutect2, varscan2
- SLC25A12 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1416103396, COSV55532216; called by muse, mutect2, varscan2
- SLC26A7 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52604772; called by muse, mutect2
- SLC44A2 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59839084; called by muse, varscan2
- SLC4A7 | c.1915-1G>C p.X639_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV55397149, COSV55402914; called by muse, mutect2, varscan2
- SLC9A4 | c.755T>G p.M252R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV99763193; called by muse, mutect2
- SLC9A8 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV64291487; called by muse, mutect2, varscan2
- SON | c.6008C>T p.S2003F | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51670863; called by muse, varscan2
- SOX5 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV58648814; called by muse, mutect2, varscan2
- SPHKAP | c.3471C>G p.S1157R | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV60894630; called by muse, mutect2, varscan2
- STAB2 | c.3725A>G p.N1242S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66347268; called by muse, varscan2
- STK24 | c.1054G>C p.G352R | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV64823792; called by muse, mutect2, varscan2
- STK36 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55330933; called by muse, mutect2
- SULF1 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV52693501; called by muse, mutect2, varscan2
- SVBP | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV65301221; called by muse, mutect2, varscan2
- SZT2 | c.2402G>T p.S801I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV65174688; called by muse, mutect2, varscan2
- TARBP2 | c.857C>G p.S286C (on ENST00000266987 / NM_134323.2; = p.S265C on NM_004178.4) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV57200759; called by muse, mutect2, varscan2
- TAS1R3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765980224, COSV59562128; called by muse, mutect2, varscan2
- TBC1D17 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV55581259, COSV55581388; called by muse, varscan2
- TBC1D17 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 75/524 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760637954, COSV55581402; called by muse, varscan2
- TBC1D17 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357484611, COSV55581412; called by muse, mutect2, varscan2
- TCEANC2 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1329527200; called by mutect2, varscan2
- TECR | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV53109211; called by muse, mutect2, varscan2
- TECTA | c.3702G>T p.Q1234H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV50807268; called by muse, mutect2, varscan2
- TENM2 | c.2935A>T p.T979S (on ENST00000518659 / NM_001122679.2; = p.T747S on NM_001080428.3) | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV69141518; called by muse, varscan2
- TES | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV64043730; called by muse, mutect2, varscan2
- TG | c.8221G>A p.E2741K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV55090726, COSV55094362; called by muse, mutect2, varscan2
- TGFBR3 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53023084, COSV53031292; called by muse, mutect2, varscan2
- TMC2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as rs758426455, COSV62651174; called by muse, mutect2, varscan2
- TMCO4 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2
- TMEM100 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV70118335; called by muse, mutect2, varscan2
- TMEM132A | c.2626C>T p.Q876* (on ENST00000453848 / NM_178031.3; = p.Q877* on NM_017870.4) | Nonsense Mutation (SNP) | VAF 59/311 reads (19%) | catalogued as rs760593541, COSV50005821; called by muse, mutect2, varscan2
- TMEM132E | c.670T>G p.Y224D (on ENST00000321639; = p.Y314D on NM_001304438.2) | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.693); catalogued as COSV58700582; called by muse, mutect2, varscan2
- TMEM248 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV58577859; called by muse, mutect2, varscan2
- TNC | c.5509A>G p.K1837E | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.065); catalogued as COSV60790625; called by muse, mutect2, varscan2
- TNFSF8 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV56344071; called by muse, varscan2
- TOX2 | c.193-1G>A p.X65_splice (on ENST00000358131 / NM_001098798.2; = p.X14_splice on NM_032883.3) | Splice Site (SNP) | VAF 33/300 reads (11%) | catalogued as COSV57890306; called by muse, mutect2, varscan2
- TP53BP2 | c.3007C>T p.H1003Y (on ENST00000343537 / NM_001031685.3; = p.H874Y on NM_005426.2) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59073106; called by muse, mutect2, varscan2
- TPO | c.1282T>A p.W428R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1161795297; called by muse, mutect2, varscan2
- TRIM36 | c.954G>C p.L318F | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56693404; called by muse, mutect2, varscan2
- TRIO | c.3509C>G p.S1170C | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100710172, COSV60096029; called by muse, mutect2, varscan2
- TRIO | c.3853G>C p.E1285Q | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60096043; called by muse, mutect2, varscan2
- TTLL7 | c.2577G>C p.L859F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV53089094; called by muse, mutect2, varscan2
- TTN | c.62263G>C p.A20755P (on ENST00000591111; = p.A13331P on NM_003319.4) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV60354625; called by muse, mutect2, varscan2
- TTN | c.25397T>C p.I8466T (on ENST00000591111; = p.I7539T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | PolyPhen benign (0.093); catalogued as rs1226202295, COSV60354663; called by muse, mutect2, varscan2
- TTN | c.4404T>G p.C1468W (on ENST00000591111; = p.C1422W on NM_003319.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | PolyPhen probably damaging (0.987); catalogued as COSV60354679; called by muse, mutect2, varscan2
- UBASH3A | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs767474940, COSV52310302; called by muse, mutect2, varscan2
- UBR5 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV55300556; called by muse, mutect2, varscan2
- ULK4 | c.1225A>T p.M409L | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV57223760; called by muse, mutect2, varscan2
- ULK4 | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57223773; called by muse, mutect2, varscan2
- UNC13A | c.4144G>A p.V1382I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV53210852; called by muse, mutect2, varscan2
- UNC5A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836784, COSV99458728; called by muse, mutect2
- USP20 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV59617891; called by muse, mutect2, varscan2
- USP48 | c.135-2A>G p.X45_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV57614851; called by mutect2, varscan2
- USP8 | c.2281C>G p.Q761E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV56168606; called by muse, mutect2, varscan2
- VPS51 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.177); catalogued as COSV54209488; called by muse, mutect2, varscan2
- ZBED4 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV53468233; called by muse, mutect2, varscan2
- ZBTB49 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61926145; called by muse, mutect2, varscan2
- ZER1 | c.1390A>G p.N464D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV52568732; called by muse, mutect2, varscan2
- ZFC3H1 | c.4824G>C p.M1608I | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV66435920; called by muse, mutect2
- ZFHX4 | c.7955G>T p.W2652L | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50747687, COSV51496723; called by muse, mutect2, varscan2
- ZFPM1 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60325859; called by muse, mutect2, varscan2
- ZMYM1 | c.3263C>A p.S1088Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63253806; called by muse, mutect2, varscan2
- ZNF148 | c.1671G>C p.E557D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV62307720; called by muse, mutect2, varscan2
- ZNF232 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 92/144 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.405); catalogued as COSV51504926; called by muse, mutect2, varscan2
- ZNF337 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1216057961, COSV53320522; called by muse, mutect2
- ZNF408 | c.1705C>T p.H569Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61239349; called by muse, mutect2, varscan2
- ZNF445 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV68538763, COSV68539676; called by muse, mutect2, varscan2
- ZNF483 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 115/123 reads (93%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV58517318; called by muse, mutect2, varscan2
- ZNF536 | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as rs1568544477, COSV62834306; called by muse, mutect2, varscan2
- ZNF620 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV58820970; called by muse, mutect2, varscan2
- ZNF816 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs909456225, COSV54412546; called by muse, mutect2, varscan2
- ADCY3 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- ADGRL2 | c.1985C>G p.S662* (on ENST00000370717 / NM_001366005.1; = p.S649* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- AGO4 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- ASF1B | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- C12orf45 | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- CCDC167 | c.192G>A p.E64= | Splice Region (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CD2 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- CD34 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- CDK5R1 | c.344C>A p.S115* | Nonsense Mutation (SNP) | VAF 81/256 reads (32%) | called by muse, mutect2, varscan2
- CREB5 | c.1459G>T p.E487* (on ENST00000357727 / NM_182898.4; = p.E480* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- CYP3A7 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- DCUN1D1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- DHRS11 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- EPHA2 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- EPX | c.1601_1605del p.A534Vfs*4 | Frame Shift Del (DEL) | VAF 27/222 reads (12%) | called by mutect2, pindel, varscan2
- FCMR | c.358dup p.L120Pfs*6 | Frame Shift Ins (INS) | VAF 17/120 reads (14%) | called by mutect2, pindel, varscan2
- GNAS | c.1392T>A p.D464E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, varscan2
- IGKV1-16 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- KIAA1109 | c.1207A>C p.R403= | Splice Region (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- KRT40 | c.222_225delinsAAAA p.G75K | Missense Mutation (ONP) | VAF 37/205 reads (18%) | called by pindel, varscan2*
- LRRC6 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- MPZ | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 55/572 reads (10%) | called by muse, mutect2
- MYEF2 | c.1109del p.G370Vfs*5 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- OPCML | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCDHAC2 | c.1835C>A p.S612* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- PREX2 | c.2589del p.F863Lfs*8 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel, varscan2
- RADX | c.1721C>A p.S574* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- RBM15 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- SRP68 | c.23del p.P8Qfs*51 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- STAG2 | c.1213_1215delinsTT p.T406Lfs*19 | Frame Shift Del (DEL) | VAF 51/103 reads (50%) | called by pindel, varscan2*
- TTN | c.97246G>T p.E32416* (on ENST00000591111; = p.E24992* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- TXK | c.447-2A>G p.X149_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- UNC5CL | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- VPS13D | c.10624G>T p.E3542* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | called by muse, mutect2, varscan2
- ZFP28 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- ZNF518A | c.3019G>C p.E1007Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); called by muse, mutect2
- ADAMTS14 | c.3648C>T p.L1216= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs200606378; called by muse, mutect2, varscan2
- ADAT1 | c.1035G>A p.L345= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV57188550; called by muse, mutect2, varscan2
- ASTN1 | c.2316C>A p.P772= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV56085735; called by muse, mutect2, varscan2
- ATPAF2 | c.642C>G p.L214= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV58266722, COSV58267006; called by muse, mutect2, varscan2
- C12orf4 | c.1503C>T p.F501= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54209772; called by muse, mutect2, varscan2
- C8orf76 | c.24C>T p.F8= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs773115630, COSV52690555, COSV52692077; called by muse, mutect2, varscan2
- CASP5 | c.339G>A p.L113= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV52831766; called by muse, mutect2, varscan2
- CBR4 | c.138C>T p.L46= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs773414726, COSV60370921; called by muse, mutect2, varscan2
- CBY2 | c.567C>G p.L189= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV60119864; called by muse, mutect2, varscan2
- CDC25B | c.1308G>A p.V436= (on ENST00000245960 / NM_021873.3; = p.V422= on NM_004358.4) | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV55659761; called by muse, mutect2, varscan2
- CELA2B | c.651T>A p.G217= | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as COSV61602535; called by muse, mutect2, varscan2
- CENATAC | c.444C>T p.I148= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV57723911; called by muse, mutect2, varscan2
- CHFR | c.1491G>A p.A497= (on ENST00000432561 / NM_001161345.1; = p.A456= on NM_018223.2) | Silent (SNP) | VAF 40/242 reads (17%) | catalogued as rs755310429, COSV57174648; called by muse, mutect2, varscan2
- CIRBP | c.87C>T p.Y29= | Silent (SNP) | VAF 44/216 reads (20%) | catalogued as rs767659188, COSV58011054, COSV58012404; called by muse, mutect2, varscan2
- CNBD2 | c.1089C>T p.F363= | Silent (SNP) | VAF 13/174 reads (7%) | catalogued as COSV62588016; called by muse, mutect2
- CPNE1 | c.468A>T p.G156= (on ENST00000352393; = p.G161= on NM_003915.5) | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV58295169; called by muse, mutect2, varscan2
- CTNND1 | c.1146C>G p.V382= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs889990491, COSV62386279; called by muse, mutect2, varscan2
- DBX1 | c.528G>A p.G176= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV57055284; called by muse, mutect2, varscan2
- DCAF4L2 | c.1020C>T p.I340= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV60481265, COSV60482711; called by muse, mutect2, varscan2
- DIS3 | c.2715T>C p.D905= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs779087641, COSV66708078; called by mutect2, varscan2
- DND1 | c.117G>A p.Q39= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs775829419, COSV56909455; called by muse, mutect2, varscan2
- DOCK3 | c.543T>C p.Y181= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as COSV56550143; called by muse, mutect2, varscan2
- EEF1D | c.564G>A p.K188= | Silent (SNP) | VAF 41/315 reads (13%) | catalogued as COSV52788941; called by muse, mutect2, varscan2
- EXOC2 | c.1152C>G p.L384= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV57871965; called by muse, mutect2, varscan2
- EZH2 | c.435C>T p.F145= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV57459127, COSV57463164; called by muse, mutect2, varscan2
- FANCA | c.3462C>T p.F1154= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV59798639; called by muse, mutect2, varscan2
- FCAMR | c.433C>T p.L145= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs1281449681, COSV61369614; called by muse, mutect2, varscan2
- FRMPD1 | c.1398C>T p.V466= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as COSV66703165; called by muse, mutect2, varscan2
- GJB7 | c.543C>T p.L181= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV51531606; called by muse, mutect2, varscan2
- GSG1 | c.534C>T p.F178= (on ENST00000651961 / NM_001080555.4; = p.H184Y on NM_031289.5) | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as COSV52192495; called by muse, mutect2, varscan2
- H4C4 | c.311G>A p.*104= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV61591371, COSV61591431; called by muse, mutect2, varscan2
- IFFO1 | c.594G>A p.S198= | Silent (SNP) | VAF 5/39 reads (13%) | called by mutect2, varscan2
- IFITM3 | c.318G>A p.L106= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as COSV60249566; called by muse, mutect2, varscan2
- JAKMIP2 | c.1647C>T p.F549= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54615725; called by muse, mutect2, varscan2
- KDM8 | c.168C>T p.F56= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV53732031; called by muse, mutect2, varscan2
- KRT12 | c.933G>A p.Q311= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as COSV52432471; called by muse, mutect2, varscan2
- KRTAP10-10 | c.705C>T p.C235= | Silent (SNP) | VAF 70/275 reads (25%) | catalogued as COSV59980431; called by muse, mutect2, varscan2
- KRTAP13-3 | c.120C>T p.L40= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs914774054, COSV61880418; called by muse, mutect2
- L3MBTL2 | c.1938G>A p.K646= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV53435787; called by muse, mutect2, varscan2
- LCA5L | c.267G>A p.V89= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as COSV55747432; called by muse, mutect2, varscan2
- MAFB | c.717G>A p.L239= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV64827125; called by muse, mutect2, varscan2
- MCL1 | c.282G>C p.A94= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57190417; called by muse, mutect2, varscan2
- MYH13 | c.2031G>C p.L677= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV52843152; called by muse, mutect2, varscan2
- MYO15A | c.5145C>T p.F1715= | Silent (SNP) | VAF 50/79 reads (63%) | catalogued as COSV52766397; called by muse, mutect2, varscan2
- MYO5B | c.4608G>A p.L1536= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV53230802; called by muse, mutect2, varscan2
- NBEA | c.6036T>C p.A2012= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV59823261; called by muse, mutect2
- NCOA3 | c.3840C>T p.F1280= (on ENST00000371998 / NM_181659.3; = p.F1276= on NM_006534.4) | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV59073508; called by muse, varscan2
- NEDD8 | c.132C>T p.I44= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV51661926; called by muse, mutect2, varscan2
- NLRP10 | c.111G>A p.L37= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs774102396, COSV60782734; called by muse, mutect2, varscan2
- NTNG1 | c.579G>A p.V193= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53988890; called by muse, mutect2, varscan2
- ODF3B | c.339G>C p.G113= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs774742528, COSV52689479, COSV52689781; called by muse, mutect2, varscan2
- OR14K1 | c.549A>G p.L183= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV51722468; called by muse, mutect2, varscan2
- OR2AK2 | c.582G>A p.Q194= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs750044627, COSV63561092; called by muse, mutect2, varscan2
- OR6C68 | c.549G>A p.L183= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1179873002, COSV65563930; called by muse, mutect2, varscan2
- OR8B4 | c.288T>C p.C96= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs142136468, COSV100635757; called by muse, mutect2, varscan2
- OTOF | c.1353C>G p.L451= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV55520218; called by muse, mutect2, varscan2
- PARVB | c.324G>A p.V108= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as COSV58691538; called by muse, mutect2, varscan2
- PCDHA2 | c.1683C>T p.N561= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV65371257; called by muse, varscan2
- PCDHGA10 | c.738C>T p.F246= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54035768; called by muse, mutect2, varscan2
- PCK1 | c.15G>A p.L5= | Silent (SNP) | VAF 44/293 reads (15%) | catalogued as COSV60131236; called by muse, mutect2, varscan2
- PDE6B | c.480C>T p.F160= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV55331019; called by muse, mutect2, varscan2
- PDGFC | c.975C>G p.T325= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56855193, COSV56855684, COSV99925158; called by muse, mutect2, varscan2
- PDHA2 | c.406C>T p.L136= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV54782044; called by muse, mutect2, varscan2
- PGAM4 | c.498C>T p.F166= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV58447032; called by muse, mutect2, varscan2
- PI3 | c.306G>A p.K102= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as COSV54782920, COSV54783822; called by muse, mutect2, varscan2
- PITPNM2 | c.552C>T p.V184= | Silent (SNP) | VAF 57/261 reads (22%) | catalogued as COSV54909004; called by muse, mutect2, varscan2
- POLR1A | c.2256G>A p.A752= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs372234146; called by muse, mutect2, varscan2
- PRDM9 | c.1377G>A p.R459= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as rs112001060, COSV57006728, COSV57010936; called by muse, mutect2, varscan2
- PRKDC | c.3870T>G p.L1290= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- PRPF6 | c.435C>G p.L145= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV53878816; called by muse, mutect2, varscan2
- PRSS21 | c.376C>T p.L126= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV50052321; called by muse, mutect2, varscan2
- PSMD3 | c.1197G>A p.R399= | Silent (SNP) | VAF 45/325 reads (14%) | catalogued as COSV52859771; called by muse, mutect2, varscan2
- PTGER2 | c.102C>T p.A34= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV55420223; called by muse, mutect2, varscan2
- PTGER4 | c.1197C>G p.L399= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV56722599; called by muse, mutect2
- RANBP10 | c.600C>G p.L200= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV58161344; called by muse, mutect2, varscan2
- RDX | c.489A>C p.L163= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV58196663; called by muse, mutect2, varscan2
- REV1 | c.3105G>A p.A1035= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs183307465, COSV51490620; called by muse, mutect2, varscan2
- RIMS1 | c.186G>A p.A62= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as rs773456988, COSV53453239; called by muse, mutect2, varscan2
- RMI2 | c.411G>A p.L137= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV56964489; called by muse, mutect2, varscan2
- RNF40 | c.2124G>A p.R708= | Silent (SNP) | VAF 60/225 reads (27%) | catalogued as COSV61216772; called by muse, mutect2, varscan2
- RPL11 | c.294C>T p.F98= (on ENST00000374550 / NM_001199802.1; = p.F99= on NM_000975.5) | Silent (SNP) | VAF 88/152 reads (58%) | catalogued as rs1059937, COSV65779048; called by muse, varscan2
- RRP12 | c.12G>A p.S4= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV59671585; called by muse, mutect2, varscan2
- RXRB | c.807C>T p.G269= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV63400044; called by mutect2, varscan2
- SHROOM2 | c.2208C>G p.P736= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV66610778; called by muse, mutect2, varscan2
- SIPA1L2 | c.2859G>A p.L953= | Silent (SNP) | VAF 108/336 reads (32%) | catalogued as rs751539554, COSV53400095; called by muse, mutect2, varscan2
- SLC12A7 | c.621G>A p.L207= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV53762638; called by muse, mutect2, varscan2
- SLC25A11 | c.771G>A p.P257= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as rs766715912, COSV52592136; called by muse, mutect2, varscan2
- SLC35F3 | c.639C>T p.L213= (on ENST00000366617 / NM_001300845.1; = p.L282= on NM_173508.4) | Silent (SNP) | VAF 251/723 reads (35%) | catalogued as rs1159088857, COSV64019810; called by muse, mutect2, varscan2
- SLC47A2 | c.972C>G p.L324= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs368229952; called by muse, mutect2, varscan2
- SLCO5A1 | c.2139C>T p.C713= | Silent (SNP) | VAF 43/278 reads (15%) | catalogued as rs757977367, COSV52668486; called by muse, mutect2, varscan2
- SOAT1 | c.681C>T p.F227= | Silent (SNP) | VAF 59/331 reads (18%) | catalogued as COSV62657101; called by muse, mutect2, varscan2
- SPHKAP | c.3747G>A p.L1249= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV60894618; called by muse, mutect2, varscan2
- SRRT | c.561C>T p.F187= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV61453829, COSV61454863; called by muse, mutect2, varscan2
- SRSF6 | c.87C>G p.L29= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV54829187; called by muse, mutect2, varscan2
- STXBP5 | c.1992C>G p.L664= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV51658304; called by muse, mutect2, varscan2
- SUCO | c.543T>A p.A181= | Silent (SNP) | VAF 192/276 reads (70%) | catalogued as COSV55271426; called by muse, mutect2, varscan2
- SYNE2 | c.7131C>G p.G2377= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV59970772; called by muse, mutect2, varscan2
- TBC1D4 | c.1839A>T p.T613= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV66492297; called by muse, mutect2, varscan2
- TLL1 | c.2880G>T p.V960= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV50325027, COSV50327204; called by muse, mutect2, varscan2
- TM7SF3 | c.687C>T p.L229= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV58004111; called by muse, mutect2, varscan2
- TRPC4AP | c.1569G>A p.K523= | Silent (SNP) | VAF 90/406 reads (22%) | catalogued as COSV52684595; called by muse, varscan2
- TTI1 | c.2898C>T p.I966= | Silent (SNP) | VAF 56/422 reads (13%) | catalogued as COSV65062413; called by muse, mutect2, varscan2
- TTN | c.25617C>G p.T8539= (on ENST00000591111; = p.T7612= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV60354653; called by muse, mutect2, varscan2
- TUBGCP3 | c.876C>G p.V292= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs968559360, COSV56191497; called by muse, mutect2, varscan2
- U2AF2 | c.732C>G p.V244= | Silent (SNP) | VAF 95/316 reads (30%) | catalogued as COSV58276394; called by muse, mutect2, varscan2
- UBE2S | c.60G>T p.V20= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV52741343, COSV99198778; called by muse, varscan2
- UBR4 | c.11196G>A p.R3732= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs1299038156, COSV64399495; called by muse, mutect2, varscan2
- UCKL1 | c.1437C>T p.I479= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs576751215, COSV62403837; called by muse, mutect2, varscan2
- UGGT1 | c.2145C>T p.F715= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV52141691, COSV99390943; called by muse, mutect2, varscan2
- UNC5A | c.1431G>A p.E477= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV52844706; called by muse, mutect2
- USH2A | c.8391A>T p.S2797= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100232542, COSV56438379; called by muse, mutect2, varscan2
- USP4 | c.376C>T p.L126= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV55540632; called by muse, mutect2, varscan2
- VASN | c.192C>T p.I64= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1198256669, COSV52034008; called by muse, mutect2, varscan2
- VEGFC | c.969C>G p.L323= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV54606938, COSV99709533; called by muse, mutect2, varscan2
- VIRMA | c.4479C>T p.L1493= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV52591436, COSV99888525; called by muse, mutect2, varscan2
- VPS13C | c.6486C>G p.L2162= (on ENST00000644861 / NM_020821.3; = p.L2119= on NM_017684.5) | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV51425267; called by muse, mutect2, varscan2
- WDR72 | c.309T>A p.A103= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV64754078; called by muse, mutect2, varscan2
- XIRP2 | c.6912G>A p.Q2304= (on ENST00000628543; = p.Q2479= on NM_152381.6) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV54735167; called by muse, mutect2, varscan2
- ZMYM1 | c.1833C>T p.F611= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1221116339, COSV63252625, COSV63253796; called by muse, varscan2
- ZNF124 | c.111C>G p.L37= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV61507982; called by muse, mutect2, varscan2
- ZNF23 | c.1893C>G p.L631= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs1393223031, COSV61841750; called by muse, mutect2
- ZNF407 | c.729C>G p.V243= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV55270486; called by muse, mutect2, varscan2
- ZNF502 | c.1584C>T p.F528= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1025916759, COSV56075178; called by muse, mutect2, varscan2
- ZNF696 | c.534G>A p.E178= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57525786; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503726 C>T | 5'Flank (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+17304C>G | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- FAM153CP | n.407G>A | RNA (SNP) | VAF 67/274 reads (24%) | catalogued as COSV67753201; called by muse, mutect2, varscan2
- FRMPD2B | n.1325G>T | RNA (SNP) | VAF 14/22 reads (64%) | called by mutect2, varscan2
- MAZ | c.1280-509C>G | Intron (SNP) | VAF 10/88 reads (11%) | catalogued as COSV50718628; called by muse, mutect2, varscan2
- OR3A4P | n.1028G>C | RNA (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.3374-1837C>T | Intron (SNP) | VAF 205/281 reads (73%) | catalogued as rs751247448, COSV100224746; called by muse, mutect2, varscan2
- PVRIG | chr7:100223654 T>A | 3'Flank (SNP) | VAF 55/298 reads (18%) | catalogued as COSV52782855; called by muse, mutect2, varscan2
- RRP7A | c.*3879C>T | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- TCF3 | c.1823-556G>A | Intron (SNP) | VAF 37/150 reads (25%) | catalogued as COSV53650160, COSV53653816; called by muse, mutect2, varscan2
- TXLNG | c.*1G>C | 3'UTR (SNP) | VAF 21/66 reads (32%) | catalogued as rs1332588305, COSV100417792; called by muse, mutect2, varscan2
